Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PS, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PS-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma, intestinal type 8144/3
Site: Stomach NOS C16.9
JES 3/7/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastric stump)

I-) Esophageal margin (stapler): uninvolved by neoplasia.

II-) Gallbladder.

- Organ exhibiting important autolysis artifacts.
- There is no apparent neoplasia on the examined material.

III-) Hepatogastric ligament: adipose tissue uninvolved by neoplasia.

IV-) Product of total gastrectomy + D1 lymphadenectomy + celiac trunk.

- Moderately differentiated adenocarcinoma (intestinal type of Lauren) involving the gastric stump, the perigastric adipose tissue and the entire depth of the small intestine wall.
- Presence of tumoral infiltration of the peritoneum.
- Presence of lymphatic tumoral infiltration.
- Venous and perineural infiltration not detected.
- Moderate stromal desmoplasia.
- Mild intratumoral inflammatory infiltrate.
- Proximal and distal margins uninvolved by neoplasia.
- Non tumoral gastric mucosae exhibiting alkaline gastritis.

D1 lymphadenectomy:

right paracardics.

- Metastatic adenocarcinoma with capsular transposition (1/1).

Left paracardics.

- Lymph nodes uninvolved by neoplasia (0/3).

Lesser curvature.

- Lymph nodes uninvolved by neoplasia (0/3).

Left gastric artery.

- Tumoral implant on the adipose tissue.
- One lymph node uninvolved by neoplasia (0/1).

Celiac trunk.

- Lymph nodes uninvolved by neoplasia (0/3).

Case ID	10-11-113	yes	No
HR-AS Discrepancy			✓
Page Malignancy History			✓
Final/Syncronous Primary Tumor			

Source: NCI Genomic Data Commons file 2aab00a7-893f-4748-9171-6500c19c0312 (TCGA-VQ-A8PS.286FB6E1-A5CC-4A9D-A69D-746F11EF5E5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).